Somatic mutation profile of tumor specimen TCGA-EM-A3ST-01A (aliquot TCGA-EM-A3ST-01A-11D-A22Z-08) from TCGA case TCGA-EM-A3ST, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.9 years (22,990 days).
Specimen TCGA-EM-A3ST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a45401-f575-44fc-95b3-7e0cd96be05e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3ST-11A (Solid Tissue Normal), aliquot TCGA-EM-A3ST-11A-11D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc625bde-265b-4d55-89ed-c3547503560b

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 3, Silent 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 62/135 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CC2D1A | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369479851; called by muse, mutect2, varscan2
- CCDC171 | c.352+1G>A p.X118_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99902300; called by muse, mutect2, varscan2
- EIF1AX | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV101096106; called by muse, mutect2, varscan2
- EIF1AX | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV101096110; called by muse, mutect2, varscan2
- GPRC5B | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100315352; called by muse, mutect2, varscan2
- GPRC5B | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV100315355; called by muse, mutect2, varscan2
- GSDMA | c.675T>A p.N225K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.089); catalogued as COSV100053848; called by muse, mutect2, varscan2
- HSPA5 | c.1861A>G p.K621E | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.068); catalogued as rs773627521, COSV52333989; called by muse, mutect2, varscan2
- LINGO1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs188738703, COSV62436676; called by muse, mutect2, varscan2
- MACF1 | c.15547G>A p.A5183T (on ENST00000372915; = p.A3116T on NM_012090.5) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99247446; called by muse, mutect2, varscan2
- RAB6B | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs201627683, COSV99558360; called by muse, mutect2, varscan2
- SHCBP1 | c.1417A>C p.T473P | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100317601; called by muse, mutect2, varscan2
- TGM4 | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99942745; called by muse, mutect2
- TTN | c.64168G>T p.E21390* (on ENST00000591111; = p.E13966* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100634728; called by muse, mutect2
- WNK2 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.812); catalogued as COSV99945078; called by muse, mutect2
- FN3KRP | c.533_538del p.D178_M179del | In Frame Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel, varscan2
- APOBEC3C | c.541C>T p.L181= | Silent (SNP) | VAF 91/224 reads (41%) | catalogued as COSV99329262; called by muse, mutect2, varscan2
- IGSF9 | c.489C>T p.S163= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100829673; called by muse, mutect2, varscan2
